Surgical pathology report (de-identified scan), TCGA case TCGA-PJ-A5Z9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Gundersen Lutheran, specimen TCGA-PJ-A5Z9-01A (Primary Tumor).

[page 1 of 2]
Patient:

Med. Record. No.:

Date of Birth:

Submitted by:

Report also to:

Age:

Sex: F

Pathology #:

Date of Procedure:

Date Received:

Pathology Report

DIAGNOSIS:

SPECIMEN

Left partial nephrectomy

TUMOR

Histologic type: Papillary renal cell carcinoma

Histologic grade (Fuhrman nuclear grade): Grade 3

Focality: Solitary within specimen

Tumor size (greatest dimension): 6cm

Extent of direct tumor invasion: No direct extension beyond kidney

Sarcomatoid component: Absent

Lymphovascular invasion (excluding renal vein): Absent

Renal vein involvement: Indeterminate
(cannot be assessed)

Pathologic findings in non-neoplastic kidney:

No additional significant pathologic findings

Adrenal: Not present

MARGINS

All margins negative for carcinoma

LYMPH NODES

Cannot be assessed

STAGING (AJCC)

Primary Tumor: pT1b

Lymph Nodes: pNX

Distant Metastasis: Not applicable

CLINICAL INFORMATION:

Left kidney mass;

research specimen

SPECIMEN(S) RECEIVED:

Left kidney mass

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NDS C64.9
J2 4/29/13

[page 2 of 2]
Patient: [REDACTED]

MRN: [REDACTED]

GROSS DESCRIPTION:

Received fresh is a 75-gram, 6.5 x 6.3 x 5.8 cm soft, nodular, red-gray partial nephrectomy covered with a few tags of golden yellow perinephric fat. The irregular, partially cauterized 5 x 4.5 cm resectional margin is inked. Sectioning reveals a soft, nodular, friable, dusky, mottled yellow-gray to red-gray 6 x 5.7 x 4.9 cm mass which appears grossly to come within 0.1 cm of the inked margin of resection. The nodular mass does not grossly appear to invade through the renal capsule. There is a narrow rim of rubbery, red-gray renal parenchyma present at the base of the specimen. Representative sections to include the inked margin are submitted in A1-A2. Additional sections to include the periphery are submitted in A3.

Slides were microscopically examined by the pathologist.

Evaluation performed by [REDACTED]

Electronically signed

Criteria	lw 2/27/13	Yes	No

Source: NCI Genomic Data Commons file cce7d5bd-1817-47a4-a603-3d22977b997f (TCGA-PJ-A5Z9.DA178E11-1799-4A7F-8D98-34D2CD639E07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).